Somatic mutation profile of tumor specimen RC-B5CS-TBP1-A (aliquot RC-B5CS-TBP1-A-1-0-D-A93N-47) from RC case RC-B5CS, project RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatosplenic T-cell lymphoma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 44.4 years (16,216 days).
Specimen RC-B5CS-TBP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a32d6abb-7ad0-424d-b573-5855f45669ee.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen RC-B5CS-NB1-A (Granulocytes; tissue type Normal), aliquot RC-B5CS-NB1-A-1-0-D-A93N-47; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8c9dbe12-46ac-47e6-8126-bd18aade5cf7

The open-access MAF lists 1 somatic variant for this specimen: 1 silent.
By variant classification: Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CLDN17 | c.270C>G p.L90= | Silent (SNP) | VAF 10/112 reads (9%) | called by mutect2, varscan2
